Surgical pathology report (de-identified scan), TCGA case TCGA-C9-A480, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site ILSBio, specimen TCGA-C9-A480-01A (Primary Tumor).

[page 1 of 6]
ICD-0-3

Clinical Case Report

(For Col)

Carcinoma, squamous cell, NOS 8070/3

Site: Tongue, NOS C02.9

hw 9/24/12

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status		Race
	1 m 52	☐ Single ☒ Married ☐ Divorced ☐ Widow		WHITE CAUCASIAN
Gender	Weight	Blood Pressure		Heart Rate
☐ Male ☒ Female	50 kg	13/8		

HISTORY OF PRESENT ILLNESS
Chief Complaints: An ulceration on the tongue that can't be cured
Symptoms:
Clinical Findings:
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☒ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 6]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☒ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		EA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☒ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 6]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray		
CT		
Endoscopy		
MRI		
Biopsy	Carcinoma	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
Tongue Cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Clinical Staging		Date of Diagnosis
T3 N0 M0		Stage: III

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
1/3 of the tongue was removed.			
Primary Tumor			
Organ	Detailed Location	Size	
Tongue Tumor	Base	5 x 2 x 1.5 cm	
Extension of Tumor			
Lymph Nodes			
Description	Location of Lymph Nodes	# of Lymph Nodes	
Palpable, Non-Dissected Lymph Nodes			
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location	Size	
Surgical Staging			
T3 N0 M0 Stage: III			

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 6]
Pathology Form

Specimen Information

Collected by: _____ Date: _____

Preserved by: _____ Date: _____

SPECIMEN TYPE (# of samples provided)							
Frozen		Paraffin Block		Blood/Serum/Plasma		Slide	
Diseased	Normal	Diseased	Normal	Diseased	Normal	Diseased	Normal
4	2	4	2			4	2
Time to LN2		Time to Formalin		Time to LN2			
10 min		11 min					

PATHOLOGICAL DESCRIPTION			
Primary Tumor			
Organ	Size	Extension of Tumor	Distance to NAT
Tongue Tumor	5 x 2 x 1.5 cm	base of tongue	3 cm
Lymph Nodes			
Location	# Examined	# Metastasized	
Distant Metastasis			
Organ	Detailed Location	Size	
Pathological Staging			
pT 3	N 0	M 0	Stage: III

Notes:

[page 5 of 6]
Microscopic Description

Histological Pattern															
Cell Distribution			+	-	Structural Pattern			+	-						
Diffuse			X		Streaming										
Mosaic					Storiform										
Necrosis					Fibrosis										
Lymphocytic Infiltration					Palisading										
Vascular Invasion					Cystic Degeneration										
Clusterized					Bleeding										
Alveolar Formation					Myxoid Change										
Indian File					Psammoma/Calcification										
Cellular Differentiation															
Squamous		+	-	Adenomatous		+	-	Sarcomatous		+	-	Lymphomatous		+	-
Squamoid Cell		X		Glandular cell				Round Cell				Large Cell			
Spindle Cell				Cell Stratification				Fibroblast				Small Cell			
Keratin		X		Secretion				Osteoblast				RS Cell/RS Like			
Desmosome				Intracyt. Vacuole				Lipoblast				Inflam. Cell			
Pearl				Gland formation				Myoblast				Plasma Cell			
Cellular Differentiation:				X Well		Moderate		Poor							
Nuclear Appearance															
Nuclear Atypia:								0	I	II	III				
Aniso Nucleosis									X						
Hyperchromatism									X						
Nucleolar Prominent										X					
Multinucleated Giant Cell										X					
Mitotic Activity									X						
Nuclear Grade:															

IHC Data			
Marker	Result	Value	Date
ER	☐ Negative ☐ Positive		
PR	☐ Negative ☐ Positive		
Her-2/neu	☐ Negative ☐ Positive		
B-Cell Marker	☐ Negative ☐ Positive		
T-Cell Marker	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		
Other:	☐ Negative ☐ Positive		

Final Pathology Report

Histological Diagnosis: Squamous cell carcinoma
(well differentiated) pT3N1M0, Stage III **Grade:** 1

Comments:

Principal Investigator

Pathologist

[page 6 of 6]
CONSOLIDATED DIAGNOSTIC PATHOLOGY FORM*

Microscopic Appearance:

1. Histological pattern:

CELL DISTRIBUTION			STRUCTURAL PATTERN		
	+	-		+	-
Diffuse		X	Streaming		
Mosaic	X		Storiform		
Necrosis		X	Fibrosis		
Lymphocytic Infiltration	X		Palisading		
Vascular Invasion		X	Cystic Degeneration		
Clusterized	X		Bleeding		
Alveolar Formation		X	Myxoid Change		
Indian File		X	Psammoma/Calcification		

2. Cellular features:

Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamous Cell	X		Glandular cell			Round Cell			Large Cell		
Spindle Cell	X		Cell Stratification			Fibroblast			Small Cell		
Keratin	X		Secretion			Osteoblast			RS Cell/RS Like		
Desmosome	X		Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl	X		Gland formation			Myoblast			Plasma Cell		

Otherwise Specified: A, 50%, D2 50%, D3 50%, D4 30%

2. Cellular Differentiation:

Well	Moderately	Poor

3. Nuclear Atypia:

Nuclear Appearance	0	I	II	III
Aniso Nucleosis		X		
Hyperchromatism		X		
Nucleolar Prominent		X		
Multinucleated Giant Cell		X		
Mitotic Activity		X		
Nuclear Grade		X		

Histological Diagnosis: Squamous Cell Carcinoma, G1

Comments: _____

Date: _____

Director, Research Pathology

*(INTEGRATED REPORT OF FINDINGS BY CONTRIBUTOR AND

THOLOGIST STAFF FOR RESEARCH USE ONLY).

Review of Initials		

12/8/2012

Source: NCI Genomic Data Commons file bd8dafe8-1c0c-4069-8e0c-9d8545f8c34a (TCGA-C9-A480.E2AD1B09-CB8B-481C-8E6B-2704B4792A1C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).